CCDI case PBCBBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c9b02ae3-44df-4f09-af33-302f2a790bd8

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.1 years (6,239 days).

Biospecimens (3 samples)
- Sample 0DMWTQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMWTW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DMWU3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
